MMRF case MMRF_2286 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/edb78746-34ff-4caf-b0b5-ef9f6d48546d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,882 days); ISS stage: II; Days to last known disease status: 811 days (2.2 years); Days to last follow up: 811 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 110 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 342 days; Days to treatment end: 342 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 343 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 473 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -48 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 26.2 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 380 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 28 g/L; Total Protein 8.4 g/dL; Glucose 5.78 mmol/L.
- Day 57 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 28 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 86: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 3.45 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.
- Day 246 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 9.77 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 2.19 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 16.3 ×10⁹/L; Absolute Neutrophil 14.7 ×10⁹/L; Platelets 385 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 29 g/L; Total Protein 7.4 g/dL; Glucose 7.26 mmol/L.
- Day 417 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 21.3 ×10⁹/L; Absolute Neutrophil 19.5 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 473: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 0.84 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 8.64 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 16 ×10⁹/L; Absolute Neutrophil 14.2 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 7.3 g/dL; Glucose 6.88 mmol/L.
- Day 557: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 6.7 g/dL; Glucose 6.77 mmol/L.
- Day 642: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 6.32 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 5.23 mmol/L.
- Day 811: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.63 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.86 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 358 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.23 mmol/L; Albumin 21 g/L; Total Protein 6.3 g/dL; Glucose 9.57 mmol/L.

Other clinical attributes
- Day -48: Weight: 90 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2286_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -48 days.
- Sample MMRF_2286_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -48 days.
